Gene-level copy-number profile of tumor specimen TCGA-3C-AALK-01A from TCGA case TCGA-3C-AALK, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IA; Age at diagnosis: 52.2 years (19,074 days).
Specimen TCGA-3C-AALK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.52dbb525-a0ad-4dce-bb51-650f97510c6e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-3C-AALK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c236e62d-3526-49f0-a2a2-216e4a6653d6

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,739; copy number 2: 53,028; copy number 3: 2,804; copy number 4: 20; copy number 5: 991; copy number 7: 96; copy number 8: 108; copy number 9: 33.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-3C-AALK-01A-11D-A41E-01): tumor purity 0.61, ploidy 2.05, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,228 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:35,344,231–35,864,615, 39 genes, copy number 5 (within-gene range 3–5): AC060766.2, SLFN11, AC060766.3, AC060766.6, AC060766.4, AC060766.7, AC060766.5, AC060766.1, SLFN12, SLFN13, AC015911.4, SLFN12L, AC015911.7, SLFN12L, AC015911.5, E2F3P1, TAF5LP1, AC015911.3, TOMM20P2, AC015911.9, AC015911.2, SLFN14, AC015911.6, AC015911.8, AC015911.1, SNHG30, SNORD7, PEX12, AP2B1, AC004134.1, TAF15, RASL10B, GAS2L2, MMP28, AC006237.1, C17orf50, AC015849.2, AC015849.3, AC015849.4.
- chr17:37,609,739–40,136,917, 108 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr17:48,382,371–83,095,122, 1,081 genes, copy number 5–9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,739. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
